Somatic mutation profile of tumor specimen TCGA-B8-4148-01A (aliquot TCGA-B8-4148-01A-02D-1386-10) from TCGA case TCGA-B8-4148, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 63.1 years (23,062 days).
Specimen TCGA-B8-4148-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb6b047e-ad47-4b56-853e-871d39dc6f10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-4148-10A (Blood Derived Normal), aliquot TCGA-B8-4148-10A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc22c6ee-39fa-4a62-90db-ecbc38ffb951

The open-access MAF lists 37 somatic variants for this specimen: 32 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 4, 5'Flank 1, In Frame Del 1, Frame Shift Ins 1, Splice Site 1, Splice Region 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV52269700; called by muse, mutect2, varscan2
- BCL9L | c.27G>A p.R9= | Splice Region (SNP) | VAF 4/24 reads (17%) | catalogued as COSV58312475; called by muse, mutect2
- CENPE | c.2532T>G p.N844K | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54381998; called by muse, mutect2
- COX19 | c.108A>T p.K36N | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.412); catalogued as COSV59937571; called by muse, mutect2, varscan2
- CTDSP2 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs776949485, COSV101143015, COSV66079941; called by muse, mutect2, varscan2
- DDX1 | c.1170G>C p.Q390H | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs1391873446, COSV51840280; called by muse, mutect2, varscan2
- EFHC2 | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 85/297 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV69553972; called by muse, mutect2, varscan2
- FBH1 | c.905G>A p.C302Y (on ENST00000362091 / NM_178150.3; = p.C353Y on NM_032807.4) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201500988, COSV62982740; called by muse, mutect2, varscan2
- FLG | c.7080C>G p.H2360Q | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.176); catalogued as COSV64242544; called by muse, mutect2, varscan2
- GNL3L | c.854G>C p.G285A | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60576540; called by muse, mutect2, varscan2
- HSPD1 | c.215A>C p.K72T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV52098879; called by muse, mutect2, varscan2
- MAGI3 | c.1596G>T p.K532N | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.527); catalogued as COSV56836560; called by muse, mutect2, varscan2
- NTRK3 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs772244244, COSV62306052; called by muse, mutect2, varscan2
- PBRM1 | c.1739A>G p.Y580C | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56279177; called by muse, mutect2, varscan2
- PCNA | c.462T>G p.I154M | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.384); catalogued as COSV52532316; called by muse, mutect2, varscan2
- POTEA | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as rs774501417; called by muse, varscan2
- RAB39B | c.470C>G p.A157G | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV65624697; called by muse, mutect2
- RELA | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58014936, COSV58015150; called by muse, mutect2, varscan2
- S1PR2 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs763068319, COSV58485445; called by muse, mutect2, varscan2
- S1PR2 | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.947); catalogued as COSV58485447; called by muse, mutect2
- SBNO1 | c.2989T>C p.S997P (on ENST00000420886; = p.S996P on NM_018183.5) | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57342079; called by muse, mutect2, varscan2
- SURF4 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs782088793, COSV64338918; called by muse, mutect2, varscan2
- TMEM225 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs907505047, COSV66693067; called by muse, mutect2, varscan2
- TMEM254 | c.7A>C p.T3P | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV64845809; called by muse, varscan2
- VCAN | c.1560G>T p.L520F | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746423250, COSV54106346, COSV54116402; called by muse, mutect2, varscan2
- ZNF383 | c.382G>C p.A128P | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV61939282; called by muse, mutect2, varscan2
- ANKRD27 | c.81_85del p.K27Nfs*26 | Frame Shift Del (DEL) | VAF 20/103 reads (19%) | called by mutect2, pindel, varscan2
- FGGY | c.982_990del p.E328_G330del | In Frame Del (DEL) | VAF 28/165 reads (17%) | called by mutect2, pindel, varscan2
- RHBDL1 | c.641_642insAA p.Y214* (on ENST00000219551 / NM_001318733.2; = p.Y149* on NM_001278720.2) | Nonsense Mutation (INS) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.998); called by muse, mutect2
- VHL | c.551dup p.Y185Lfs*71 | Frame Shift Ins (INS) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- ZEB1 | c.684+3_684+6del p.X228_splice | Splice Site (DEL) | VAF 10/32 reads (31%) | called by pindel, varscan2
- EDN1 | c.171C>T p.S57= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV65080807; called by muse, mutect2, varscan2
- OR51I2 | c.252C>G p.T84= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV100413305; called by muse, mutect2
- PCDHB3 | c.561C>T p.D187= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs374383309; called by muse, mutect2, varscan2
- TP53BP2 | c.423A>G p.A141= (on ENST00000343537 / NM_001031685.3; = p.A12= on NM_005426.2) | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as rs764316574, COSV59068984; called by muse, mutect2, varscan2
- TTLL10 | chr1:1169079 A>G | 5'Flank (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
